Gene-level copy-number profile of tumor specimen TCGA-LQ-A4E4-01A from TCGA case TCGA-LQ-A4E4, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 73.6 years (26,883 days).
Specimen TCGA-LQ-A4E4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.77cf9295-680b-433c-98b6-022747c28474.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LQ-A4E4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/681cd6b0-37cd-4962-9777-82622b2f34b2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,494; copy number 2: 43,427; copy number 3: 2,757; copy number 4: 37; copy number 6: 105.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LQ-A4E4-01A-11D-A25N-01): tumor purity 0.84, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 105 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:179,183,734–183,635,783, 102 genes, copy number 6 (broad region; genes not listed).
- chr1:183,646,275–183,754,937, 3 genes, copy number 6: APOBEC4, AL157899.1, AL590422.1.

Autosomal genes at a single copy (total copy number 1): 11,073. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
